Surgical pathology report (de-identified scan), TCGA case TCGA-L5-A893, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University of Michigan, specimen TCGA-L5-A893-01A (Primary Tumor).

[page 1 of 3]
ICD-O-3
Adenocarcinoma NOS 8140/3
Site: Distal third of esophagus
615.5
9/11/12/13

ACCESSION:

OPER DATE:

REQ DOC:

PROCEDURE:

VERIFIED BY:

year-old female with distal esophageal Barrett's adenocarcinoma, long history of GERD, S/P laparoscopic NISSEN fundoplication. Hiatal hernia 4 to 5 cm. History of smoking, stopped prior to the surgery. Barium swallow 3 cm sliding hiatal hernia. Clinical diagnosis: Esophageal CA. Operative procedure: Transhiatal esophagectomy.

PROCEDURE:

VERIFIED

1. "Thoracic esophagus" Received in formalin is a gastroesophagectomy specimen. The esophagus is 3.0 cm long x 3.0 cm in diameter and a portion of proximal stomach is 4.0 cm long x 4.5 cm in diameter. Located 2.0 cm from the esophageal margin and 4.0 cm from the distal gastric margin. At the area of the GE junction is a 2.5 x 1.5 cm tan-pink, firm and well-defined mass that is shiny to granular and extends 0.5 cm from the mucosal surface. The mass occupies 50% of the circumference. Sectioning reveals the mass to extend 0.6 cm below the surface and grossly abut the muscularis propria but does not extend through. The wall is thickened adjacent to the mass. The remaining esophageal mucosa is tan-pink and unremarkable. The remaining gastric mucosa is normally folded, tan and unremarkable. Examination of the attached adipose tissue reveals multiple probable lymph nodes that range from 0.5 up to 0.9 cm in greatest dimension.

1A. Distal margin.

1B. Mass to esophageal mucosa.

1C. Mass to gastric mucosa.

1D. Tumor showing deepest invasion.

[page 2 of 3]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:
BIRTHDATE:

PATIENT NBR:

PAGE #: 3
SEX: F
ADM DATE:

ACCESSION:

OPER DATE:

REQ DOC:

- 1E. Adjacent thickened wall.
- 1F. Four possible nodes, one bisected.
- 1G. Four possible nodes, one bisected.
- 2. "Mid left para-esophageal LN" Received in formalin is a 1.0 x 0.6 x 0.4 cm yellow-black lymph node. Bisected.
- 3. "Prox cervical esoph margin" Received in formalin is a 1.0 cm long x 2.0 cm in diameter segment of mucosal tissue that has a 2.5 cm long staple margin at one end. The staple margin is removed. The mucosa is tan-white and glistening.

PROCEDURE:

VERIFIED BY:

ESOPHAGEAL, CARDIAC AND GASTROESOPHAGEAL JUNCTION CARCINOMA:

Type of carcinoma: Poorly differentiated carcinoma.

If adenocarcinoma, it is arising in: Barrett's mucosa.

Depth of invasion: Submucosa.

Number of positive lymph nodes: 0

Extranodal metastasis: Unknown.

Specify site: _

Pattern of invasion: Expansile.

Esophageal and gastric resection margins involved: No.

Deep resection margin involved: No.

TNM classification: T1 N0 M0

PROCEDURE:

VERIFIED BY:

- 1. "Esophagus, resection: Poorly differentiated carcinoma arising in Barrett's mucosa. Tumor invades submucosa. Margins negative. Nine lymph nodes negative for metastasis. Please see template.
- 2. Mid left para-esophageal lymph nodes, resection: One lymph node negative for metastasis.
- 3. Proximal cervical esophagus, resection: Negative for malignancy.

[page 3 of 3]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:
BIRTHDATE:

PATIENT NBR:

PAGE #: 4
SEX: F
ADM DATE:

ACCESSION:

OPER DATE:

REQ DOC:

I, , the signing staff pathologist, have personally examined and interpreted the slides from this case.

Code:

Criteria:	10/21/12	No
Same Site (Recs):	QUALIFIED	10/21/12

Source: NCI Genomic Data Commons file fff40daa-3838-4920-8fea-5540a3f44842 (TCGA-L5-A893.8020952F-2364-4902-BC90-CBFD14CF41C3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).